Gene-level copy-number profile of tumor specimen TCGA-MP-A4TK-01A from TCGA case TCGA-MP-A4TK, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.3 years (20,581 days).
Specimen TCGA-MP-A4TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.529f7325-0169-445e-b279-628aaa5e15e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MP-A4TK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/56933992-5370-4dbd-a6e4-f419649a7388

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 6,727; copy number 2: 37,295; copy number 3: 11,675; copy number 4: 2,796; copy number 5: 379; copy number 6: 656; copy number 7: 83; copy number 8: 78; copy number 9: 16; copy number 13: 28; copy number 16: 22; copy number 20: 15; copy number 21: 24; copy number 31: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MP-A4TK-01A-11D-A24O-01): tumor purity 0.34, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,921,328–117,027,039, 4 genes: AC069504.1, LINC00901, RNU5E-8P, PTMAP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,317 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,236,967–152,445,456, 119 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr2:175,022,214–176,102,489, 18 genes, copy number 5 (within-gene range 4–5): RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1, EXTL2P1, AC016751.2, AC016751.1, LNPK, EVX2, HOXD13, HOXD12.
- chr4:38,276,178–38,945,739, 16 genes, copy number 7 (within-gene range 3–7): AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574.
- chr5:58,198–20,616,441, 358 genes, copy number 6 (broad region; genes not listed).
- chr8:30,983,459–31,033,715, 2 genes, copy number 5 (within-gene range 1–5): AC008066.1, PURG.
- chr8:32,192,028–32,448,803, 3 genes, copy number 7: RNA5SP262, RNA5SP263, NRG1-IT3.
- chr9:28,539,735–30,575,012, 11 genes, copy number 6: AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1.
- chr9:75,198,071–75,724,575, 4 genes, copy number 5: RNU6-1228P, AL158073.1, AL353780.1, OTX2P1.
- chr10:20,779,973–21,743,630, 22 genes, copy number 6 (within-gene range 4–6): NEBL, MTND1P21, AL157398.1, EIF4BP2, NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1, RNU6-15P, LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915, SKIDA1, MLLT10, AL358780.1, RNU6-306P, HNRNPRP1, RNU6-1141P.
- chr11:23,154,683–26,663,289, 26 genes, copy number 5 (within-gene range 3–5): LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1, AC079064.1, MUC15.
- chr12:26,120,030–32,896,777, 158 genes, copy number 5–6 (broad region; genes not listed).
- chr12:57,512,688–64,397,065, 128 genes, copy number 6–21 (within-gene range 2–21) (broad region; genes not listed).
- chr12:67,443,105–68,234,686, 13 genes, copy number 9 (within-gene range 2–9): LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG.
- chr12:68,842,197–73,208,317, 69 genes, copy number 5–31 (within-gene range 2–31) (broad region; genes not listed).
- chr12:75,275,979–75,390,928, 1 gene, copy number 8 (within-gene range 3–8): CAPS2.
- chr12:75,333,798–75,984,015, 12 genes, copy number 8 (within-gene range 2–8): AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:78,052,181–78,359,746, 3 genes, copy number 6: AC073571.1, PRXL2AP1, LINC02424.
- chr14:30,734,926–38,041,442, 140 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr17:13,755,574–14,297,600, 9 genes, copy number 5: COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1, COX10, SNORA74, CDRT15, AC005224.1.
- chr17:14,303,854–14,305,505, 1 gene, copy number 5: AC005224.3.
- chr17:14,705,076–15,744,778, 36 genes, copy number 5 (within-gene range 3–5): RPS18P12, AC013248.1, AC005863.1, LINC02096, RPL23AP76, AC005772.1, CDRT7, AC005772.2, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1.
- chr22:27,276,240–28,742,422, 27 genes, copy number 5 (within-gene range 2–5): AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P, CHEK2.
- chr22:35,400,134–35,553,999, 4 genes, copy number 5 (within-gene range 3–5): MCM5, AL022334.1, AL022334.2, RASD2.
- chr22:40,346,500–44,172,939, 137 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
